Gene-level copy-number profile of tumor specimen TCGA-66-2727-01A from TCGA case TCGA-66-2727, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 55.2 years (20,150 days).
Specimen TCGA-66-2727-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.30e831e0-9401-4314-be19-6984e86cee5b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-66-2727-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/48305638-4c9c-412b-af07-c5805f52ff75

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 86; copy number 1: 224; copy number 2: 10,636; copy number 3: 13,521; copy number 4: 26,651; copy number 5: 4,601; copy number 6: 1,878; copy number 7: 15; copy number 8: 1,055; copy number 9: 220; copy number 10: 459; copy number 11: 412; copy number 12: 28; copy number 13: 6; copy number 14: 19; copy number 26: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-66-2727-01A-01D-0978-01): tumor purity 0.47, ploidy 3.73, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 86 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:54,874,605–54,967,088, 2 genes (within-gene range 0–2): CACNA2D3-AS1, LRTM1.
- chr4:181,237,358–181,265,145, 2 genes: AC019235.1, LINC02500.
- chr8:150,584–5,142,707, 69 genes (broad region; genes not listed).
- chr9:4,070,906–4,071,884, 1 gene: AL359095.1.
- chr9:28,148,211–28,149,236, 1 gene: AL451124.1.
- chr10:99,875,577–100,009,947, 2 genes (within-gene range 0–2): DNMBP, DNMBP-AS1.
- chr11:9,754,770–10,294,219, 7 genes (within-gene range 0–4): LINC02709, SBF2-AS1, SBF2, AC011092.2, RNU7-28P, AC011092.1, AC011092.3.
- chr11:99,020,949–100,358,885, 1 gene (within-gene range 0–2): CNTN5.
- chr11:100,336,856–100,337,625, 1 gene: RPA2P3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,146 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:59,987,269–60,073,770, 1 gene, copy number 10 (within-gene range 4–10): C1orf87.
- chr2:177,255,945–177,265,515, 2 genes, copy number 26: MIR3128, AC079305.1.
- chr3:93,843,764–97,752,460, 28 genes, copy number 12 (within-gene range 8–12): RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6.
- chr3:99,817,837–107,240,671, 68 genes, copy number 10–14 (within-gene range 8–14) (broad region; genes not listed).
- chr3:141,487,027–141,615,344, 1 gene, copy number 11 (within-gene range 6–11): RASA2.
- chr3:141,600,276–142,713,664, 27 genes, copy number 11 (within-gene range 6–11): YWHAQP6, LINC02618, TPT1P3, AC112771.1, RNF7, AC112504.2, GRK7, AC112504.3, HMGN2P25, ATP1B3, RNU6-509P, ATP1B3-AS1, AC112504.1, TFDP2, AC133435.1, RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P, ATR, AC109992.1, AC109992.2, RPL6P9, RNA5SP143, PLS1, PLS1-AS1.
- chr3:148,791,102–149,752,495, 32 genes, copy number 10 (within-gene range 6–10): CPB1, HMGB1P30, AC092979.1, CPA3, AC092979.2, UBQLN4P1, GYG1, HLTF, HLTF-AS1, Y_RNA, MED28P2, HPS3, CP, AC093001.2, CPHL1P, AC093001.1, TM4SF18, AC073522.1, TM4SF1, TM4SF1-AS1, AC108751.4, AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1, COMMD2.
- chr3:151,079,506–157,677,749, 116 genes, copy number 10 (broad region; genes not listed).
- chr3:175,938,929–188,154,057, 265 genes, copy number 9–10 (broad region; genes not listed).
- chr3:188,178,543–188,180,812, 1 gene, copy number 10: FLJ42393.
- chr3:188,688,781–198,222,513, 218 genes, copy number 9–11 (broad region; genes not listed).
- chr5:10,971,836–29,983,114, 211 genes, copy number 9 (broad region; genes not listed).
- chr8:36,378,069–38,853,028, 67 genes, copy number 11 (within-gene range 2–11) (broad region; genes not listed).
- chr8:39,584,489–43,674,591, 100 genes, copy number 11 (broad region; genes not listed).
- chr13:86,725,500–87,458,407, 6 genes, copy number 13: TXNL1P1, LINC00430, UBBP5, LIN28AP2, AL360267.2, AL360267.1.
- chr13:93,032,972–93,227,317, 3 genes, copy number 9: LINC00363, AL354811.2, AL354811.1.

Autosomal genes at a single copy (total copy number 1): 224. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
